Gene-level copy-number profile of tumor specimen TCGA-85-7843-01A from TCGA case TCGA-85-7843, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 50.2 years (18,353 days).
Specimen TCGA-85-7843-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.c2364af1-ef69-4a76-9040-7743df2bacc6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-7843-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a93ee436-35a0-404c-ad56-2c722be21762

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 8; copy number 2: 1,691; copy number 3: 1,960; copy number 4: 25,010; copy number 5: 6,310; copy number 6: 10,812; copy number 7: 5,957; copy number 8: 4,556; copy number 9: 242; copy number 10: 717; copy number 11: 256; copy number 12: 643; copy number 13: 81; copy number 14: 311; copy number 15: 963; copy number 16: 159; copy number 23: 17; copy number 31: 69; copy number 32: 44.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-7843-01A-11D-2121-01): tumor purity 0.41, ploidy 5.38, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:4,317,388–4,503,392, 2 genes: AC027251.1, AC010941.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,502 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:96,349,554–97,752,460, 10 genes, copy number 14–16 (within-gene range 3–16): HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1, EPHA6.
- chr3:146,059,585–198,222,513, 928 genes, copy number 11–15 (broad region; genes not listed).
- chr4:49,486,926–53,460,862, 40 genes, copy number 10: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25, DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1.
- chr4:58,780,626–61,153,962, 17 genes, copy number 9–13 (within-gene range 7–13): AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1, Y_RNA, AC096588.1, AC093857.1, Y_RNA, RNU6-1325P, AC092596.1, AC097655.1, LINC02496, AC105420.1, MIR548AG1, LINC02271.
- chr4:61,211,652–61,212,203, 1 gene, copy number 13: RPL17P19.
- chr4:62,071,752–63,143,881, 10 genes, copy number 10–13: ADGRL3-AS1, RPS15AP17, AC007511.1, RPL21P47, AC105313.1, AC074087.2, AC074087.1, HMGN1P11, EXOC5P1, AC097491.1.
- chr5:58,198–45,895,970, 710 genes, copy number 11–12 (broad region; genes not listed).
- chr6:66,710,242–67,210,480, 3 genes, copy number 10: AL450336.1, RNU7-66P, AL591004.1.
- chr8:34,874,159–35,093,509, 2 genes, copy number 14: AC087343.1, AC099685.1.
- chr8:35,254,344–35,256,605, 1 gene, copy number 14: AC090740.1.
- chr8:37,421,341–43,674,591, 168 genes, copy number 16–31 (within-gene range 5–31) (broad region; genes not listed).
- chr8:91,101,832–91,398,155, 4 genes, copy number 12 (within-gene range 7–12): LRRC69, CPP, MIR4661, SLC26A7.
- chr9:34,179,005–34,252,523, 1 gene, copy number 10 (within-gene range 6–10): UBAP1.
- chr9:34,223,984–35,483,035, 58 genes, copy number 10: AL353662.1, KIF24, RNU2-50P, SERPINH1P1, NUDT2, MYORG, C9orf24, Y_RNA, FAM219A, DNAI1, RN7SKP24, ENHO, AL160270.1, AL160270.2, CNTFR, CNTFR-AS1, RPP25L, DCTN3, ARID3C, SIGMAR1, GALT, AL162231.3, IL11RA, CCL27, AL162231.4, AL162231.1, AL162231.2, CCL19, AL162231.5, CCL21, FAM205A, AL589645.1, FAM205BP, FAM205C, GLULP4, YWHAZP6, PHF24, DNAJB5-DT, DNAJB5, AL355377.1, AL355377.2, SYF2P2, AL355377.3, AL355377.4, AL353795.3, C9orf131, RN7SL338P, VCP, FANCG, PIGO, AL353795.2, STOML2, FAM214B, AL353795.1, UNC13B, AL160274.1, ATP8B5P, ZFAND6P1.
- chr9:35,491,133–35,491,969, 1 gene, copy number 10: AL133476.1.
- chr11:54,591,480–59,127,412, 230 genes, copy number 9 (broad region; genes not listed).
- chr11:69,294,151–71,252,577, 46 genes, copy number 23–32 (within-gene range 8–32): MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr12:30,696,121–34,163,442, 91 genes, copy number 10–11 (broad region; genes not listed).
- chr12:34,190,471–34,249,958, 4 genes, copy number 9: AC140847.2, RNA5SP357, DUX4L27, AK6P1.
- chr14:32,076,114–32,272,301, 7 genes, copy number 11 (within-gene range 4–11): ARHGAP5, AL161665.1, AL161665.2, RNU6-7, RNU6-8, AL136298.2, KIAA1143P1.
- chr14:32,373,337–32,484,800, 3 genes, copy number 11: AL136298.1, RN7SL660P, MTCO1P2.
- chr14:33,924,227–34,462,774, 1 gene, copy number 11 (within-gene range 6–11): EGLN3.
- chr14:34,416,687–37,596,059, 85 genes, copy number 11–14 (broad region; genes not listed).
- chr14:37,720,425–37,720,561, 1 gene, copy number 13: AL136296.1.
- chr14:95,876,392–106,875,071, 568 genes, copy number 10 (broad region; genes not listed).
- chr16:22,814,162–23,064,173, 3 genes, copy number 10 (within-gene range 4–10): HS3ST2, AC127459.2, AC127459.1.
- chr16:23,061,767–23,062,232, 1 gene, copy number 10: AC127459.3.
- chr16:89,575,758–90,222,851, 34 genes, copy number 13 (within-gene range 8–13): CPNE7, DPEP1, CHMP1A, SPATA33, AC010538.1, CDK10, LINC02166, SPATA2L, VPS9D1, VPS9D1-AS1, ZNF276, FANCA, SPIRE2, TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3, DEF8, CENPBD1, AFG3L1P, DBNDD1, GAS8, GAS8-AS1, URAHP, PRDM7, TUBB8P7, FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.
- chr17:34,479,272–35,325,449, 28 genes, copy number 13: AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1, AC022903.1, CCT6B, AC022903.2, ZNF830, LIG3, RFFL, AC004223.3, AC004223.4, AC004223.2, AC004223.1, RAD51D, RNU6-840P, Vault, FNDC8, NLE1, UNC45B, AC022916.4, AC022916.2, AC022916.3, SLC35G3, AC022916.1, SLFN5, AC022706.1.
- chr17:71,596,338–72,237,203, 10 genes, copy number 10: AC118653.1, MYL6P5, AC007432.1, AC005144.1, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9.
- chr17:72,342,692–72,355,136, 1 gene, copy number 10: LINC02003.
- chr19:27,638,483–39,428,415, 424 genes, copy number 11–16 (broad region; genes not listed).
- chr21:22,882,582–23,281,909, 7 genes, copy number 16: AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1, RNU2-55P.
- chr21:41,986,831–42,143,453, 4 genes, copy number 9 (within-gene range 4–9): ZBTB21, ZNF295-AS1, UMODL1, UMODL1-AS1.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
